Surgical pathology report (de-identified scan), TCGA case TCGA-BF-AAP1, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-AAP1-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** Male

Clinical diagnosis: Melanoma

Date of procurement:

Sample:

Gross description:

The material presented – non-pigmented skin from right hand surgical resection

Microscopic description:

Received material is skin patch with malignant melanoma 11x8x3 cm in the center of the mushroom formation of dark brown color with patches of ulceration, measuring 2x2.5 cm, rises by 1.5 cm above the surface. Amelanotic melanoma, ulcerated, nodular form, epithelioid, Clark-IV, Breslow - 15 mm.

Final diagnosis: Amelanotic, ulcerated, nodular form, epithelioid melanoma

ICD O-3
Melanoma, amelanotic nodular
epithelioid cell
8771/3 8730/3 8721/3
Code to highest 8771/3
Site: Skin @ hand C44.6
JW 4/22/14

Pw TSS, non-glabrous.

Confidential

Dual/Synchronous Pathology Noted		

Source: NCI Genomic Data Commons file 76c5d041-2992-4bb6-b711-268bcdd63098 (TCGA-BF-AAP1.FAAB1959-5595-4FE8-8EAD-EB753B658F03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).